Somatic mutation profile of tumor specimen TCGA-D3-A2JA-06A (aliquot TCGA-D3-A2JA-06A-11D-A196-08) from TCGA case TCGA-D3-A2JA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.9 years (25,907 days).
Specimen TCGA-D3-A2JA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6804c34e-5e0d-4f89-8304-d39049eb4fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JA-10A (Blood Derived Normal), aliquot TCGA-D3-A2JA-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e558eac3-b11f-44a5-900d-16e9e5bf9ddd

The open-access MAF lists 413 somatic variants for this specimen: 278 protein-altering or splice-affecting, 123 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 123, Nonsense Mutation 12, Intron 8, Splice Region 7, Frame Shift Del 3, Splice Site 2, 5'UTR 1, Translation Start Site 1, 3'Flank 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56984819, COSV56985325; called by muse, mutect2, varscan2
- ERBB4 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs776347334, COSV61460793; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1555491648, CM138230, COSV58019167, COSV58047483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV60198076; called by muse, mutect2, varscan2
- AC008676.3 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV56635733; called by muse, mutect2, varscan2
- AC013489.1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV51550027; called by muse, mutect2, varscan2
- AC126283.2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM086400, CM136036, COSV101143955, COSV67097792; called by muse, mutect2, varscan2
- ACSL1 | c.1434C>T p.G478= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as COSV55660493; called by muse, mutect2, varscan2
- ACTN2 | c.2594G>A p.R865K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100856629; called by muse, mutect2, varscan2
- ADAM18 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55843485, COSV55846117; called by muse, mutect2, varscan2
- ADAMDEC1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56473962; called by muse, mutect2, varscan2
- ADAMTS10 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99546603; called by muse, mutect2, varscan2
- ADAMTS14 | c.870C>T p.I290= | Splice Region (SNP) | VAF 15/73 reads (21%) | catalogued as rs145552242, COSV64599489; called by muse, mutect2, varscan2
- ADAMTS19 | c.1192C>T p.H398Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs865889004, COSV50731733; called by muse, mutect2, varscan2
- ADCY8 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53895566; called by muse, mutect2, varscan2
- ADGRL3 | c.3319C>T p.L1107F (on ENST00000506720 / NM_001322402.2; = p.L1039F on NM_015236.6) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1341554623, COSV72229178; called by muse, mutect2, varscan2
- AGAP1 | c.1841C>T p.S614L (on ENST00000304032 / NM_001037131.3; = p.S561L on NM_014914.5) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs1358295159, COSV58316816; called by muse, mutect2, varscan2
- ANKRD36B | c.1160A>G p.Q387R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs771084732, COSV51529936; called by muse, mutect2, varscan2
- AP2A2 | c.708C>T p.I236= | Splice Region (SNP) | VAF 62/137 reads (45%) | catalogued as rs765985458, COSV59957921; called by muse, mutect2, varscan2
- APLNR | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV57241301; called by muse, mutect2, varscan2
- APOB | c.7579G>A p.D2527N | Missense Mutation (SNP) | VAF 175/883 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.159); catalogued as COSV51922271; called by muse, mutect2, varscan2
- ARID1A | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61371289; called by muse, mutect2, varscan2
- ARL8A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1329256934, COSV55342675; called by muse, mutect2
- ATP8B3 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.096); catalogued as rs770743536, COSV59539736; called by muse, mutect2, varscan2
- ATXN7L3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66988500; called by muse, mutect2, varscan2
- B4GALNT3 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56749524; called by muse, mutect2, varscan2
- BEST2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV50358527; called by muse, mutect2, varscan2
- BGN | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV59035844; called by muse, mutect2, varscan2
- BIN1 | c.1652C>T p.P551L (on ENST00000316724 / NM_001320642.1; = p.P412L on NM_004305.4) | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1335019359, COSV52115613; called by muse, mutect2, varscan2
- CACNA1E | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs576927174, COSV62381521; called by muse, mutect2, varscan2
- CACNA1S | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV62935831, COSV62938978; called by muse, mutect2, varscan2
- CARD17 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV65214519; called by muse, mutect2, varscan2
- CBX8 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV53935338; called by muse, mutect2, varscan2
- CCDC39 | c.601A>G p.S201G | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV56478176; called by muse, mutect2, varscan2
- CD209 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV52649423; called by muse, mutect2, varscan2
- CD300A | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60409440; called by muse, mutect2, varscan2
- CDC42 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV59661096; called by muse, mutect2, varscan2
- CDH17 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV50325519; called by muse, mutect2, varscan2
- CEACAM5 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.784); catalogued as COSV55750352; called by muse, mutect2, varscan2
- CFHR5 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99888219; called by muse, mutect2, varscan2
- CHST8 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1448667265, COSV52856014; called by muse, mutect2, varscan2
- CKAP5 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56363746; called by muse, mutect2, varscan2
- CNTN5 | c.111T>G p.I37M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV54278801; called by muse, mutect2
- CNTNAP4 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV56663657; called by muse, mutect2, varscan2
- CNTNAP4 | c.3094C>T p.H1032Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56663738, COSV56690517; called by muse, mutect2
- CNTNAP5 | c.3194T>C p.V1065A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70471359; called by muse, mutect2, varscan2
- COMP | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55873747; called by muse, mutect2, varscan2
- COP1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58162717; called by muse, mutect2, varscan2
- CRLF1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100678969; called by muse, mutect2, varscan2
- CTSE | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV63059668; called by muse, mutect2, varscan2
- CUL9 | c.6532G>C p.G2178R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); catalogued as COSV52724982; called by muse, mutect2, varscan2
- CYP3A4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV60500907; called by muse, mutect2, varscan2
- DCDC1 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.451); catalogued as COSV60833569; called by muse, mutect2, varscan2
- DDX60L | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52708528; called by muse, mutect2, varscan2
- DEPP1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53573307; called by muse, mutect2, varscan2
- DISP3 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53819800; called by muse, mutect2, varscan2
- DNAH2 | c.9609G>A p.M3203I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV66716043; called by muse, mutect2, varscan2
- DNAJC13 | c.6476T>C p.I2159T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV53445250; called by muse, mutect2, varscan2
- DNM3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62452725; called by muse, mutect2
- DPH6 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1310540683, COSV56612336; called by muse, mutect2, varscan2
- DSC1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV57141426; called by muse, mutect2, varscan2
- DSG3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs1361767559, COSV57124023; called by muse, mutect2, varscan2
- DTNBP1 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59037018; called by muse, mutect2, varscan2
- EDC4 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV59301610; called by muse, mutect2
- ELAC2 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62031659, COSV62033029; called by muse, mutect2, varscan2
- ELF5 | c.602G>A p.G201E (on ENST00000312319 / NM_198381.2; = p.G191E on NM_001422.4) | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56628199; called by muse, mutect2, varscan2
- ELOA2 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55293008; called by muse, mutect2, varscan2
- EMC10 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58541568; called by muse, mutect2
- ENPP3 | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV62952863; called by muse, mutect2, varscan2
- EPAS1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.352); catalogued as COSV55383969; called by muse, mutect2, varscan2
- EPHA3 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.054); catalogued as rs1233786675, COSV60693371, COSV60707181; called by muse, mutect2, varscan2
- EPHA6 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs765684158, COSV67558187; called by muse, mutect2
- EPHB6 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.691); catalogued as COSV67417190; called by muse, mutect2, varscan2
- EPO | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53161012; called by muse, mutect2, varscan2
- EPPK1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV101599771; called by muse, mutect2
- EPPK1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV101599772; called by muse, mutect2
- ESPL1 | c.1816A>G p.I606V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775293865, COSV57757197; called by muse, mutect2, varscan2
- EXOC6 | c.217T>A p.F73I | Missense Mutation (SNP) | VAF 115/518 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53318922; called by muse, mutect2, varscan2
- FABP7 | c.75C>A p.G25= | Splice Region (SNP) | VAF 24/56 reads (43%) | catalogued as rs762435776, COSV62956380; called by muse, mutect2, varscan2
- FAM131B | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV68125420; called by muse, mutect2, varscan2
- FAM83B | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs267601082, COSV60919114; called by muse, mutect2, varscan2
- FNDC8 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.212); catalogued as COSV99338694; called by muse, mutect2, varscan2
- FREM2 | c.1283T>A p.M428K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV54827603; called by muse, mutect2, varscan2
- FRMD4B | c.2176C>T p.L726F | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1368350567, COSV68328196; called by muse, mutect2, varscan2
- FRMPD2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs746192606, COSV59714920; called by muse, mutect2, varscan2
- FRMPD3 | c.4660C>T p.P1554S | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52186073; called by muse, mutect2, varscan2
- GALP | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV61999158; called by muse, mutect2, varscan2
- GAN | c.1667A>C p.H556P | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV73720709; called by muse, mutect2, varscan2
- GIMAP6 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 141/457 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV61032382; called by muse, mutect2, varscan2
- GJB4 | c.335A>T p.N112I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV58355362; called by muse, mutect2, varscan2
- GNAS | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs966479648, COSV58326877; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GRIN2C | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV53109563; called by muse, mutect2, varscan2
- GRM2 | c.490A>G p.S164G | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583112; called by muse, mutect2, varscan2
- GRXCR1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV67669907; called by muse, mutect2, varscan2
- GSTCD | c.1844C>T p.S615F (on ENST00000360505 / NM_001031720.3; = p.S528F on NM_024751.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV64732092; called by muse, mutect2, varscan2
- GTPBP4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672685, COSV62550157; called by muse, mutect2
- GYS1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748140171, COSV54401180; called by muse, mutect2, varscan2
- HMGB4 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99587299; called by muse, mutect2, varscan2
- HMGB4 | c.413A>C p.E138A | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99587301; called by muse, mutect2, varscan2
- HOXA2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV56065052; called by muse, mutect2, varscan2
- HRH1 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67954985; called by muse, mutect2, varscan2
- HSD17B2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs779171937, COSV52274204; called by muse, mutect2, varscan2
- HTT | c.5792C>T p.S1931F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV61857160; called by muse, mutect2, varscan2
- IFNA1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV52806379; called by muse, mutect2, varscan2
- IGHG4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs756452414; called by muse, mutect2, varscan2
- IGSF1 | c.2282G>A p.W761* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as COSV63835921; called by muse, mutect2, varscan2
- IQSEC1 | c.2461T>G p.Y821D | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56220927; called by muse, mutect2, varscan2
- ITGA9 | c.1446T>G p.C482W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53235524; called by muse, mutect2, varscan2
- ITGAM | c.1713G>A p.R571= (on ENST00000648685 / NM_001145808.2; = p.R570= on NM_000632.4) | Splice Region (SNP) | VAF 47/199 reads (24%) | catalogued as COSV54933657; called by muse, varscan2
- JAM2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762937687, COSV57255251; called by muse, mutect2, varscan2
- JMJD1C | c.6364C>T p.P2122S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59512511; called by muse, mutect2, varscan2
- KCNB1 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV65565868; called by muse, mutect2, varscan2
- KCND3 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM1212997, COSV56174632; called by muse, mutect2, varscan2
- KCNJ3 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54530935; called by muse, mutect2, varscan2
- KCNT2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV54063186; called by muse, mutect2, varscan2
- KCTD14 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.307); catalogued as rs377147362, COSV62001020; called by muse, mutect2, varscan2
- KIAA1755 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV54073440, COSV99642089; called by muse, mutect2, varscan2
- KIAA2026 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs773896228, COSV67353177; called by muse, mutect2, varscan2
- KPRP | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64220904; called by muse, mutect2, varscan2
- KRT3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751579090, COSV58814476; called by muse, mutect2, varscan2
- KRT84 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs747946695, COSV57770506; called by muse, mutect2, varscan2
- KRTAP10-1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59951134; called by muse, mutect2, varscan2
- KSR2 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60365480; called by muse, mutect2, varscan2
- LAMA5 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV53360579; called by muse, mutect2
- LFNG | c.1111C>T p.P371S (on ENST00000222725 / NM_001040167.2; = p.P242S on NM_002304.2) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs772859078, COSV99761707; called by muse, mutect2, varscan2
- LGALS13 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV55679396, COSV99694886; called by muse, mutect2, varscan2
- LGR6 | c.1244C>T p.P415L (on ENST00000367278 / NM_001017403.1; = p.P363L on NM_021636.3) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV99706255, COSV99706353; called by muse, mutect2
- LIMA1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs772093224, COSV100372306; called by muse, mutect2, varscan2
- LIMA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100372308; called by muse, mutect2, varscan2
- LRP2 | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV55539946; called by muse, mutect2, varscan2
- LRP5 | c.1220C>G p.A407G | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.46); catalogued as COSV53710916; called by muse, mutect2, varscan2
- LSM4 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs748477177, COSV53253282; called by muse, mutect2, varscan2
- LTA4H | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV57381546; called by muse, mutect2, varscan2
- MAGEC3 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1370979321, COSV53575865, COSV53579184; called by muse, mutect2, varscan2
- MAST4 | c.1684C>T p.R562* (on ENST00000403625 / NM_001164664.2; = p.R373* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs1220527593, COSV55115087; called by muse, mutect2
- MAST4 | c.6592C>T p.P2198S (on ENST00000403625 / NM_001164664.2; = p.P2009S on NM_015183.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.037); catalogued as rs1259641843, COSV99843347; called by muse, mutect2
- MCM8 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61752704, COSV54510153; called by muse, mutect2, varscan2
- MDGA2 | c.2398C>T p.R800C (on ENST00000399232 / NM_001113498.2; = p.R502C on NM_182830.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776310493, COSV62078486; called by muse, mutect2, varscan2
- MECOM | c.136A>T p.T46S (on ENST00000468789 / NM_001105078.4; = p.T234S on NM_004991.4) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.239); catalogued as COSV52959035; called by muse, mutect2, varscan2
- MED12L | c.1836C>G p.F612L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56367853; called by muse, mutect2, varscan2
- MGAT4A | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.278); catalogued as COSV53845201; called by muse, mutect2, varscan2
- MMP13 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV52823010; called by muse, mutect2, varscan2
- MORC1 | c.1173C>T p.S391= | Splice Region (SNP) | VAF 23/84 reads (27%) | catalogued as rs200644565, COSV51713573; called by muse, mutect2, varscan2
- MOV10L1 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.894); catalogued as COSV53167103; called by muse, mutect2, varscan2
- MTMR7 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372780967; called by muse, mutect2, varscan2
- MUC16 | c.22972C>T p.P7658S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs1008148917, COSV67443029; called by muse, mutect2, varscan2
- MUC16 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV67443043, COSV67456684; called by muse, mutect2, varscan2
- MYO3A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564535973, COSV56318987, COSV99778053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs971448209, COSV55711595; called by muse, mutect2, varscan2
- NBPF1 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 100/720 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV55321224, COSV99844906; called by muse, varscan2
- NBR1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57830649; called by muse, mutect2, varscan2
- NCAM1 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57510117; called by muse, mutect2, varscan2
- NCOR2 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as COSV62292823; called by muse, mutect2, varscan2
- NDUFAF2 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56936104; called by muse, mutect2, varscan2
- NF1 | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as rs866069972, CM040782, COSV62192268; called by muse, mutect2
- NFKBIZ | c.1687C>T p.H563Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58199236; called by muse, mutect2, varscan2
- NLRP4 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV56707442; called by muse, mutect2, varscan2
- NLRP8 | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52583063; called by muse, mutect2, varscan2
- NPAS1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV71383825; called by muse, mutect2
- NSL1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs753892117, COSV65324691; called by muse, mutect2, varscan2
- NXF1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as rs780115078, COSV53672884, COSV99585658; called by muse, mutect2, varscan2
- OBSL1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV54712388; called by muse, mutect2, varscan2
- OR2T12 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.037); catalogued as rs146983185, COSV58775981, COSV58777031; called by muse, mutect2, varscan2
- OR51B2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV60915845; called by muse, mutect2, varscan2
- OR6C4 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.044); catalogued as COSV67792744; called by muse, mutect2, varscan2
- OR6F1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as rs745386565, COSV57466714; called by muse, mutect2, varscan2
- OTOF | c.2254G>A p.E752K (on ENST00000272371 / NM_194248.3; = p.E5K on NM_004802.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV55495050; called by muse, mutect2, varscan2
- PARP14 | c.2249C>G p.A750G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV71734081; called by muse, mutect2, varscan2
- PCDHGA11 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.269); catalogued as COSV53895157; called by muse, mutect2, varscan2
- PCLO | c.12104A>G p.Y4035C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759222848, COSV61614782; called by muse, mutect2, varscan2
- PCLO | c.6196G>A p.E2066K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61614790; called by muse, mutect2, varscan2
- PCLO | c.3413C>T p.P1138L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs1011566440, COSV100436416, COSV61614795; called by muse, mutect2, varscan2
- PCLO | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 85/248 reads (34%) | catalogued as COSV61614801; called by muse, mutect2, varscan2
- PCMTD2 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55058974; called by muse, mutect2, varscan2
- PDE1C | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV58502752; called by muse, mutect2, varscan2
- PDZD8 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53688365; called by muse, mutect2, varscan2
- PEG3 | c.2720G>C p.S907T | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.418); catalogued as COSV55624119; called by muse, mutect2, varscan2
- PITHD1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.055); catalogued as COSV55754342; called by muse, mutect2, varscan2
- PKHD1L1 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV65736536; called by muse, mutect2, varscan2
- PKLR | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61360268, COSV61362740; called by muse, mutect2, varscan2
- PLA1A | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347498536, COSV56330274; called by muse, mutect2, varscan2
- PLCE1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV53335856; called by muse, mutect2, varscan2
- PLCH2 | c.2387T>C p.L796P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53938899; called by muse, mutect2, varscan2
- PLEKHH1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV61283225; called by muse, mutect2, varscan2
- POT1 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62927889; called by muse, mutect2, varscan2
- PRAG1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV58157214; called by muse, mutect2, varscan2
- PREX1 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 207/439 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64247625; called by muse, mutect2, varscan2
- PRR23B | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV61493110; called by muse, mutect2
- PRRC2A | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV63224292; called by muse, mutect2, varscan2
- PRRX1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53410732, COSV53413286; called by muse, mutect2, varscan2
- PSMA1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV67165680; called by muse, mutect2, varscan2
- PSME4 | c.4373C>T p.S1458F | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66362982; called by muse, mutect2, varscan2
- PTPRC | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61406072; called by muse, mutect2, varscan2
- PWWP2B | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as COSV59448843; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3227T>A p.V1076D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62782026; called by muse, mutect2
- RAB6B | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53311949; called by muse, mutect2, varscan2
- RANBP3L | c.1119A>G p.I373M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV56954150; called by muse, mutect2, varscan2
- RAPGEF6 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57239750; called by muse, mutect2, varscan2
- RECK | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV65034540; called by muse, mutect2, varscan2
- RGS7BP | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.806); catalogued as rs151111266; called by muse, mutect2, varscan2
- RIMS1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.031); catalogued as rs980168624, COSV53437715; called by muse, mutect2
- RNF103 | c.445A>T p.I149L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV52893546; called by muse, mutect2, varscan2
- ROR1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as rs780850122, COSV64283723; called by muse, mutect2, varscan2
- RP1 | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs746666137, COSV55109585; called by muse, mutect2, varscan2
- RSPH6A | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as COSV55569851; called by muse, mutect2, varscan2
- RTL9 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV71825370; called by muse, mutect2, varscan2
- RYR2 | c.6248C>G p.A2083G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV63659491, COSV63686039, COSV63719384; called by muse, mutect2, varscan2
- SACS | c.4223T>C p.L1408P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV66533627; called by muse, mutect2, varscan2
- SAP130 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 107/176 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV52094047, COSV99385493; called by muse, mutect2, varscan2
- SCNN1A | c.1636A>T p.T546S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV57433908; called by muse, mutect2, varscan2
- SEC14L3 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1199816282, COSV53177817; called by muse, mutect2, varscan2
- SEC16A | c.1586G>A p.S529N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV51521249; called by muse, mutect2, varscan2
- SEL1L2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53147678, COSV99532884; called by muse, mutect2, varscan2
- SERPINA4 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54068718, COSV54069076; called by muse, mutect2, varscan2
- SF3A2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV55553487, COSV99678213; called by muse, mutect2, varscan2
- SGCZ | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV65994801, COSV66016153; called by muse, mutect2, varscan2
- SIPA1L3 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs141105353; called by muse, mutect2, varscan2
- SLC2A9 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV53316257; called by muse, mutect2, varscan2
- SLC38A1 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101284280, COSV67062866; called by muse, mutect2, varscan2
- SLC38A10 | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55842368; called by muse, mutect2, varscan2
- SLC4A9 | c.898C>T p.R300C (on ENST00000507527 / NM_001258428.2; = p.R276C on NM_031467.3) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1245745759, COSV50183759, COSV50184127; called by muse, mutect2, varscan2
- SMPDL3A | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755094; called by muse, mutect2, varscan2
- SNCAIP | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54401745; called by muse, mutect2, varscan2
- SPAG16 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 97/188 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59070187; called by muse, mutect2, varscan2
- SPEM1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV57208828; called by muse, mutect2, varscan2
- SSH1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV58454463; called by muse, mutect2, varscan2
- ST6GAL2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 158/244 reads (65%) | PolyPhen possibly damaging (0.815); catalogued as rs200701778, COSV64525934, COSV64529952; called by muse, mutect2, varscan2
- ST8SIA1 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53950182; called by muse, mutect2, varscan2
- STIL | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54547439; called by muse, mutect2, varscan2
- STKLD1 | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV64311662; called by muse, mutect2, varscan2
- STXBP5L | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 32/53 reads (60%) | catalogued as COSV56499155; called by muse, mutect2, varscan2
- SYNE1 | c.13208C>T p.S4403L (on ENST00000367255 / NM_182961.4; = p.S4332L on NM_033071.3) | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs139490297; called by muse, mutect2, varscan2
- SYNE4 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV99430915; called by muse, mutect2, varscan2
- SYNE4 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as COSV99430916; called by muse, mutect2, varscan2
- SYT10 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs761260104, COSV57337233; called by muse, mutect2, varscan2
- TCF12 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV51003304; called by muse, mutect2, varscan2
- TENM2 | c.3853C>T p.P1285S (on ENST00000518659 / NM_001122679.2; = p.P1046S on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV69122387; called by muse, mutect2
- TENM3 | c.4666G>T p.V1556L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.935); catalogued as COSV69298875; called by muse, mutect2, varscan2
- TEX19 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as COSV61016849; called by muse, mutect2, varscan2
- TEX35 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs753558646, COSV51102988; called by muse, mutect2, varscan2
- TEX43 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100847462, COSV64035896; called by muse, mutect2, varscan2
- TIAM2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.668); catalogued as COSV59689029; called by muse, mutect2
- TM4SF19 | c.450-1G>A p.X150_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56556104; called by muse, mutect2
- TMPRSS15 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs752722928, COSV53034510; called by muse, mutect2, varscan2
- TOP1 | c.2046-1G>A p.X682_splice | Splice Site (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100793716, COSV63693576; called by muse, mutect2, varscan2
- TOP1 | c.2046G>A p.K682= | Splice Region (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100793717, COSV63695889; called by muse, mutect2, varscan2
- TOP2B | c.4694C>T p.S1565F (on ENST00000264331 / NM_001330700.2; = p.S1560F on NM_001068.3) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV51968360; called by muse, mutect2, varscan2
- TP73 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV60698244; called by muse, mutect2, varscan2
- TRPM7 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV57913026; called by muse, mutect2, varscan2
- TTC23L | c.964T>C p.Y322H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV72205738; called by muse, mutect2, varscan2
- TTC29 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs756698953, COSV100283377; called by muse, mutect2, varscan2
- TTN | c.99682G>A p.E33228K (on ENST00000591111; = p.E25804K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | PolyPhen benign (0.197); catalogued as rs563430855, COSV59874413; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6890G>A p.G2297E (on ENST00000591111; = p.G2251E on NM_003319.4) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | PolyPhen probably damaging (1); catalogued as COSV59874453; called by muse, mutect2, varscan2
- TTN | c.6457G>A p.A2153T (on ENST00000591111; = p.A2107T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs747598396, COSV100610870, COSV59874498; called by muse, mutect2, varscan2
- TUBB4A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51155846; called by muse, mutect2, varscan2
- UPK3A | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV53413738; called by muse, mutect2, varscan2
- URB2 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1329241507, COSV50981070; called by muse, mutect2, varscan2
- URGCP | c.1631C>T p.P544L (on ENST00000453200 / NM_001077663.3; = p.P535L on NM_017920.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99787065; called by muse, mutect2, varscan2
- VPS72 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 43/228 reads (19%) | catalogued as COSV63166789; called by muse, mutect2, varscan2
- WASHC4 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV100162268; called by muse, varscan2
- XPO4 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55003694; called by muse, mutect2, varscan2
- YARS2 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1458956697, COSV56771996; called by muse, mutect2, varscan2
- ZFPM2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs1316717585, COSV65872466, COSV65873719; called by muse, mutect2, varscan2
- ZNF106 | c.1111A>T p.K371* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV55513350; called by muse, mutect2, varscan2
- ZNF12 | c.1301A>G p.E434G (on ENST00000405858 / NM_016265.4; = p.E396G on NM_006956.3) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61243613; called by muse, mutect2, varscan2
- ZNF208 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs1047125116, COSV68100072; called by muse, mutect2, varscan2
- ZNF596 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV57652774; called by muse, mutect2, varscan2
- ZSCAN1 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV56601383; called by muse, mutect2, varscan2
- ZSCAN5B | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as rs751914884, COSV61999163; called by muse, mutect2, varscan2
- ZSWIM4 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54319102; called by muse, mutect2, varscan2
- ARMC8 | c.1126del p.R376Gfs*10 (on ENST00000469044 / NM_001363941.2; = p.R362Gfs*4 on NM_014154.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 150/506 reads (30%) | called by mutect2, pindel*, varscan2
- IGHV3-35 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- IGLV2-18 | c.205A>C p.I69L | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- NPY2R | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBAK | c.1584del p.H529Tfs*178 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- TRBV29-1 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZNF155 | c.686_705del p.E229Afs*9 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- ABCA4 | c.5034G>A p.V1678= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs765954640, COSV64670888; called by muse, mutect2
- ABCC8 | c.249C>T p.F83= | Silent (SNP) | VAF 279/578 reads (48%) | catalogued as rs1463898525, COSV56845894; called by muse, mutect2, varscan2
- AC131160.1 | c.873C>T p.I291= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV57699861; called by muse, mutect2, varscan2
- ACTN2 | c.2595G>A p.R865= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1481193038, COSV100856631; called by muse, mutect2, varscan2
- ADIPOR1 | c.387C>T p.F129= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV61850820; called by muse, mutect2, varscan2
- AKAP4 | c.1722C>T p.T574= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV62073572; called by muse, mutect2, varscan2
- ARHGEF10L | c.573C>T p.V191= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs576561341, COSV63415132; called by mutect2, varscan2
- ARMC6 | c.1431C>T p.A477= (on ENST00000392336; = p.A452= on NM_033415.4) | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs762144965, COSV54180122; called by muse, mutect2, varscan2
- ARRB2 | c.1179G>A p.R393= | Silent (SNP) | VAF 73/144 reads (51%) | catalogued as COSV52616420; called by muse, mutect2, varscan2
- BANK1 | c.1746G>A p.E582= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV59837948; called by muse, mutect2, varscan2
- C1QC | c.255G>A p.G85= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV65889228; called by muse, mutect2, varscan2
- CAB39L | c.474C>T p.I158= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV61713444; called by muse, mutect2, varscan2
- CACNA2D2 | c.2901C>T p.F967= (on ENST00000479441 / NM_001174051.3; = p.F960= on NM_006030.4) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1241015631, COSV56560240; called by muse, mutect2, varscan2
- CCDC73 | c.1929G>A p.Q643= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV58795132; called by muse, mutect2, varscan2
- CCN3 | c.234G>A p.L78= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV52383004; called by muse, mutect2, varscan2
- CD2AP | c.1707C>T p.I569= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV63759105; called by muse, mutect2, varscan2
- CEP72 | c.291C>T p.L97= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV53789881; called by muse, mutect2, varscan2
- CKM | c.930G>A p.E310= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV53461244, COSV53463003; called by muse, mutect2, varscan2
- CNTNAP4 | c.2823C>T p.T941= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV56663694; called by muse, mutect2, varscan2
- CNTNAP5 | c.768C>T p.P256= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as COSV70471352; called by muse, mutect2, varscan2
- COLGALT2 | c.885C>T p.P295= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV100730585, COSV62298476; called by muse, mutect2, varscan2
- CRLF1 | c.897C>T p.A299= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs1219404057, COSV62260763; called by muse, mutect2, varscan2
- CUX2 | c.1986C>T p.I662= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs891516606, COSV55623848; called by muse, mutect2
- CYP4F12 | c.456G>A p.T152= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs373355202; called by muse, mutect2, varscan2
- CZIB | c.186C>T p.S62= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53758636; called by muse, mutect2, varscan2
- DDX49 | c.295C>T p.L99= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV53229382, COSV99447434; called by muse, mutect2, varscan2
- DDX60 | c.186C>T p.L62= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV67094949; called by muse, mutect2, varscan2
- DEFA6 | c.294C>T p.C98= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV52405716; called by muse, varscan2
- DNAH5 | c.7045C>T p.L2349= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54202703; called by muse, mutect2, varscan2
- DSC1 | c.813A>G p.E271= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV57141455; called by muse, mutect2, varscan2
- EGLN1 | c.96C>A p.R32= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV64147754, COSV64149642; called by muse, mutect2, varscan2
- EMC10 | c.528G>A p.V176= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100618450; called by muse, mutect2
- EPS8L3 | c.1317C>A p.P439= | Silent (SNP) | VAF 63/330 reads (19%) | catalogued as COSV62608698; called by muse, mutect2, varscan2
- FAM47C | c.2292G>A p.P764= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs1357638692, COSV63723511; called by muse, mutect2, varscan2
- FNDC4 | c.612G>A p.K204= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV53020650; called by muse, mutect2, varscan2
- FNDC8 | c.417C>G p.P139= | Silent (SNP) | VAF 73/144 reads (51%) | catalogued as COSV99338696; called by muse, mutect2, varscan2
- FRZB | c.564G>A p.K188= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV54552761, COSV54552822; called by muse, mutect2, varscan2
- GABRB3 | c.1374C>T p.F458= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54649708; called by muse, mutect2, varscan2
- GATAD1 | c.411C>T p.I137= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55319194; called by muse, mutect2, varscan2
- GGA1 | c.75C>T p.L25= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs778002231, COSV57328781; called by muse, mutect2, varscan2
- GLT6D1 | c.726C>T p.F242= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV65626957; called by muse, mutect2, varscan2
- GRIN3A | c.837C>T p.F279= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as rs1446206302, COSV62450379; called by muse, mutect2, varscan2
- HECW1 | c.1926T>C p.N642= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV67821236; called by muse, mutect2, varscan2
- HGD | c.72C>T p.S24= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV52195883; called by muse, mutect2, varscan2
- HIPK1 | c.2907G>A p.L969= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV61245685; called by muse, mutect2, varscan2
- HNF4G | c.417C>T p.V139= (on ENST00000354370 / NM_001330561.2; = p.V186= on NM_004133.5) | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs1401738198, COSV62965536; called by muse, mutect2, varscan2
- IQCH | c.399G>A p.S133= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs772348012, COSV60048798; called by muse, mutect2, varscan2
- KDR | c.2826G>A p.G942= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV55757573; called by muse, mutect2, varscan2
- KEL | c.234G>A p.E78= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV62333141, COSV62335839; called by muse, mutect2
- KIF6 | c.1404G>A p.L468= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV54666021; called by muse, mutect2, varscan2
- KRT2 | c.1020C>T p.S340= | Silent (SNP) | VAF 34/159 reads (21%) | catalogued as COSV59008977, COSV59009359; called by muse, mutect2, varscan2
- KRT6B | c.468C>T p.I156= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV52881796; called by muse, mutect2, varscan2
- LRP1B | c.9648G>A p.G3216= | Silent (SNP) | VAF 33/179 reads (18%) | catalogued as COSV67184421; called by muse, mutect2, varscan2
- MAML3 | c.684C>T p.P228= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV59070793; called by muse, mutect2, varscan2
- MAP3K6 | c.2649C>T p.L883= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as rs1414708535, COSV58870026; called by muse, mutect2, varscan2
- MCM7 | c.1647C>T p.S549= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1339783350, COSV57993778; called by muse, mutect2, varscan2
- MECOM | c.2742G>A p.K914= (on ENST00000468789 / NM_001105078.4; = p.K1102= on NM_004991.4) | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV52959022; called by muse, mutect2, varscan2
- MORC1 | c.2598C>T p.F866= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs138551884, COSV51718636; called by muse, mutect2, varscan2
- MUC16 | c.8229G>A p.S2743= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV101198441, COSV67443037; called by muse, mutect2, varscan2
- MYCN | c.1296C>A p.S432= | Silent (SNP) | VAF 47/253 reads (19%) | catalogued as rs747603773, COSV55257534, COSV55258725; called by muse, mutect2, varscan2
- MYEOV | c.240C>T p.L80= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV58293414; called by muse, mutect2, varscan2
- NHLH1 | c.135C>T p.A45= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs778981648, COSV57483091; called by muse, mutect2, varscan2
- NLRP9 | c.864G>A p.R288= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs1446400712, COSV60459277; called by muse, mutect2, varscan2
- NXF1 | c.1521G>A p.R507= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs1179148780, COSV99585874; called by muse, mutect2, varscan2
- OR1B1 | c.432C>T p.A144= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100506545, COSV59171104; called by muse, mutect2, varscan2
- OR1D2 | c.310C>T p.L104= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as COSV100513880; called by muse, mutect2, varscan2
- OR1D2 | c.309C>T p.F103= | Silent (SNP) | VAF 69/150 reads (46%) | catalogued as COSV58921543; called by muse, mutect2, varscan2
- OR2L2 | c.144C>T p.I48= | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as COSV63547703, COSV63552745; called by muse, mutect2, varscan2
- OR4A5 | c.759C>T p.F253= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV60521402, COSV60521592; called by muse, mutect2
- OR5T2 | c.474T>C p.A158= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as COSV57587709; called by muse, mutect2, varscan2
- OR8K1 | c.204C>T p.F68= | Silent (SNP) | VAF 64/111 reads (58%) | catalogued as COSV54401320; called by muse, mutect2, varscan2
- OR8K1 | c.582C>T p.L194= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV54401334; called by muse, mutect2, varscan2
- PAPPA2 | c.4980G>A p.L1660= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs773000091, COSV100868139, COSV62790332; called by muse, mutect2, varscan2
- PAXIP1 | c.2040C>T p.V680= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV68184674; called by muse, mutect2, varscan2
- PCDHA3 | c.1326C>T p.S442= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs782486389, COSV63538674; called by muse, mutect2
- PCNT | c.2271G>A p.E757= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV64024796; called by muse, mutect2, varscan2
- PDGFRB | c.1141C>T p.L381= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55800445; called by muse, mutect2, varscan2
- PLA2R1 | c.582T>G p.R194= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV51774617; called by muse, varscan2
- PLAAT1 | c.387C>T p.F129= (on ENST00000650797; = p.F24= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as rs563532190, COSV53233555; called by muse, mutect2, varscan2
- PLCE1 | c.1719C>T p.P573= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV53335872; called by muse, mutect2, varscan2
- PLEKHH1 | c.843C>T p.S281= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100232826, COSV61285583; called by muse, mutect2, varscan2
- PLEKHH2 | c.894C>T p.S298= | Silent (SNP) | VAF 154/476 reads (32%) | catalogued as COSV56749459; called by muse, mutect2, varscan2
- PLXNA3 | c.2616G>A p.V872= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV63753100; called by muse, mutect2, varscan2
- POM121L12 | c.576C>T p.F192= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs762091356, COSV68692173; called by muse, mutect2, varscan2
- PPP1R15A | c.60C>T p.F20= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1380629431, COSV52338285; called by muse, mutect2, varscan2
- PRNP | c.246A>G p.G82= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs62643364; ClinVar: benign; called by muse, varscan2
- PRSS35 | c.303A>G p.Q101= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as COSV63800053; called by muse, mutect2, varscan2
- PTPRK | c.4116G>A p.T1372= (on ENST00000368215 / NM_001291984.2; = p.T1373= on NM_002844.4) | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs138416879; called by muse, mutect2, varscan2
- PTPRN2 | c.1608C>T p.L536= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs761416498, COSV67021148; called by muse, mutect2, varscan2
- QSOX2 | c.1899C>T p.L633= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV62393316; called by muse, mutect2, varscan2
- RAD17 | c.1707C>T p.T569= (on ENST00000380774 / NM_133339.2; = p.T558= on NM_002873.1) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV51456024; called by muse, mutect2, varscan2
- RASA4 | c.1066C>T p.L356= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV99499885; called by muse, mutect2, varscan2
- RBP3 | c.1233G>A p.V411= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1555211178; called by muse, mutect2, varscan2
- RNASEH2A | c.733C>T p.L245= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV55551160; called by muse, mutect2, varscan2
- ROS1 | c.3915C>T p.I1305= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV63851064, COSV63856868; called by muse, mutect2, varscan2
- RYR1 | c.4470C>T p.N1490= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV62088148; called by muse, mutect2, varscan2
- RYR3 | c.3213C>T p.I1071= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101213327, COSV66777068; called by muse, mutect2, varscan2
- SALL1 | c.2235G>A p.T745= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs778105407, COSV51752928; called by muse, mutect2, varscan2
- SDK1 | c.5325G>T p.L1775= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101268918; called by muse, varscan2
- SEZ6L | c.1446G>A p.T482= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs142670064, COSV50657759; called by muse, mutect2, varscan2
- SIPA1 | c.1230G>A p.T410= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs1055582141, COSV67745398; called by muse, mutect2, varscan2
- SLC41A3 | c.669C>T p.P223= | Silent (SNP) | VAF 55/253 reads (22%) | catalogued as COSV59986854; called by muse, mutect2, varscan2
- SLIT3 | c.3885G>A p.T1295= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs776928464, COSV100266084, COSV60591689; called by muse, mutect2, varscan2
- SLX4 | c.5163C>T p.S1721= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV53560632, COSV99567888; called by muse, mutect2
- SMG9 | c.834C>T p.I278= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV54213412; called by muse, mutect2, varscan2
- STAB2 | c.6072C>T p.I2024= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs1248887491, COSV66333782; called by muse, mutect2, varscan2
- TAPBPL | c.534A>T p.P178= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56945843; called by muse, mutect2, varscan2
- TBCE | c.625C>T p.L209= (on ENST00000366601; = p.L272= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV64005078, COSV64007618; called by muse, mutect2, varscan2
- TEDC2 | c.732C>T p.L244= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV53537631; called by muse, mutect2, varscan2
- TENM1 | c.1161G>A p.E387= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs1402592486, COSV64424580; called by muse, mutect2, varscan2
- TMPRSS11E | c.576C>T p.I192= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as rs1353476169, COSV59517810; called by muse, mutect2, varscan2
- TPO | c.834C>T p.A278= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs773103037, COSV61093977; called by muse, mutect2, varscan2
- TRPS1 | c.2557C>T p.L853= (on ENST00000220888 / NM_001330599.2; = p.L866= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs906907658, COSV55225385; called by muse, mutect2, varscan2
- TTC29 | c.330G>A p.L110= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100283378; called by muse, mutect2, varscan2
- TXNDC2 | c.525G>A p.K175= (on ENST00000306084 / NM_001098529.2; = p.K108= on NM_032243.6) | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as rs376219011; called by muse, varscan2
- UNC13A | c.2118G>A p.G706= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV53187721; called by muse, mutect2, varscan2
- UNC13C | c.2469G>A p.E823= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV52841981; called by muse, mutect2
- URGCP | c.1632C>T p.P544= (on ENST00000453200 / NM_001077663.3; = p.P535= on NM_017920.4) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs370884647, COSV99787063; called by muse, mutect2, varscan2
- VIRMA | c.1305C>T p.T435= | Silent (SNP) | VAF 62/119 reads (52%) | catalogued as COSV52581482; called by muse, mutect2, varscan2
- VPS54 | c.1689C>T p.S563= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs201606303, COSV55437262; called by muse, mutect2, varscan2
- VPS9D1 | c.1188C>T p.G396= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV66993882; called by muse, mutect2, varscan2
- ZDHHC2 | c.519C>A p.L173= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs774921599, COSV50497227; called by muse, mutect2, varscan2
- ZNF479 | c.282C>T p.T94= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as COSV100482537; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846195 C>T | 5'Flank (SNP) | VAF 30/58 reads (52%) | catalogued as rs1396487365; called by muse, mutect2, varscan2
- DST | c.21999+442C>T | Intron (SNP) | VAF 29/68 reads (43%) | catalogued as rs756227570, COSV54996371; called by muse, mutect2, varscan2
- LHCGR | c.162-1614G>A | Intron (SNP) | VAF 71/205 reads (35%) | catalogued as rs188540939, COSV54301152; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397540 G>A | 3'Flank (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- MIR133A2 | n.34G>A | RNA (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- NEBL | c.164+46500C>T | Intron (SNP) | VAF 20/86 reads (23%) | catalogued as COSV65797642; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2730G>A | Intron (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100051901; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2104C>T | Intron (SNP) | VAF 26/78 reads (33%) | catalogued as COSV99194862; called by muse, mutect2, varscan2
- RMDN2 | c.452+22071T>G | Intron (SNP) | VAF 48/146 reads (33%) | catalogued as COSV52221916; called by muse, mutect2, varscan2
- RORA | c.196+63694G>A | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as rs779480778, COSV99832332; called by muse, mutect2, varscan2
- SWI5 | c.-96C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV60791472; called by muse, mutect2, varscan2
- THSD4 | c.-80+14249C>G | Intron (SNP) | VAF 12/55 reads (22%) | catalogued as COSV62492997; called by muse, mutect2, varscan2
